Gene-level copy-number profile of tumor specimen C3L-01000-04 from CPTAC case C3L-01000, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 59.7 years (21,800 days).
Specimen C3L-01000-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1ed45909-33b1-4117-b0c1-afcdcbbea8d5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01000-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/0ecacd67-e3f3-403b-9d52-395f12724dd5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 499; copy number 1: 15,800; copy number 2: 34,193; copy number 3: 4,647; copy number 4: 3,675; copy number 5: 14; copy number 6: 12; copy number 15: 7; copy number 20: 61; copy number 21: 7.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:33,808,778–33,810,767, 1 gene: AC136428.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 101 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:37,095,150–39,417,378, 68 genes, copy number 15–20 (broad region; genes not listed).
- chr8:145,047,860–145,066,685, 2 genes, copy number 5: AC139103.1, C8orf33.
- chr9:60,914,407–61,453,030, 12 genes, copy number 6: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P.
- chr14:37,197,913–38,041,442, 10 genes, copy number 5 (within-gene range 3–5): MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1, TTC6, AL136296.1, RNU6-1277P, LINC00517, AL359233.1.
- chr15:30,254,402–30,254,508, 1 gene, copy number 5: RNU6-17P.
- chr15:30,344,307–30,420,429, 8 genes, copy number 5–21: AC019322.4, CHRFAM7A, AC019322.1, U8, AC019322.3, GOLGA8R, RN7SL196P, AC019322.2.

Autosomal genes at a single copy (total copy number 1): 13,808. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
